CCDI case PBBYCC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/0ddde35c-e356-4db6-a7f5-1eafbdab0c6a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma in adenomatous polyposis coli: ICD-O-3 morphology code: 8220/3; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 14.9 years (5,453 days).

Biospecimens (2 samples)
- Sample 0DQZ3C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQZ3P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
